Clinical report (de-identified scan), EXCEPTIONAL_RESPONDERS case ER-ABOM, project EXCEPTIONAL_RESPONDERS-ER (Exceptional Responders), specimen ER-ABOM-TTP1-A (Primary Tumor).

[page 1 of 13]
Patient Name: [REDACTED]

MR #: [REDACTED]

Date of Birth: [REDACTED]

Submitting Physician: [REDACTED]

Account: [REDACTED]

Age: [REDACTED]

Sex: [REDACTED]

Case Number: [REDACTED]

Collection Date: [REDACTED]

Received Date: [REDACTED]

Location: MSIC

+0

+0

Physicians

REGISTRY, TUMOR; [REDACTED]

Tissue Source

CYTOLOGY FNA, lung, left lower lobe-Fine Needle Aspiration

Clinical Information

Lesion of lung

Gross Description

Received fresh by the pathologist in Radiology is a fine needle aspirate of the lung, left lower lobe. Needle washings (utilizing cytolyt) of 15 cc's of pink fluid are obtained. One Thin Prep is prepared from the needle washing material. Ten air-dried slides were prepared and stained with Diff-Quik.

Immediate Cytologic Evaluation

Received are 8 air dried slides which are stained with Diff-Quik.

Immediate Cytologic Interpretation: Few atypical cells and benign bronchial epithelial cells.

C
Y
T
O
L
O
G
Y

R
E
P
O
R
T

Diagnosis

CYTOLOGY FNA, lung, left lower lobe-Fine Needle Aspiration

POSITIVE FOR MALIGNANCY

RARE VARIABLY SIZED GROUPS OF CELLS COMPATIBLE WITH ADENOCARCINOMA

(SEE COMMENT AND CONCURRENT RESECTION SPECIMEN [REDACTED])

[page 2 of 13]
PROTOCOL #9671

Pathologist's Comment

The direct smears are hypocellular and contain rare atypical cells and bronchial epithelial cells.
The Thin-prep smear contains rare groups of cells consistent with adenocarcinoma.

Electronic Signature

C
Y
T
O
L
O
G
Y

R
E
P
O
R
T

[page 3 of 13]
Patient Name: [REDACTED]
MR#: [REDACTED] Account: [REDACTED]
Date of Birth: [REDACTED] Age: [REDACTED] Sex: [REDACTED]
Submitting Physician: [REDACTED]

Case Number: [REDACTED]
Collection Date: [REDACTED] +0
Received Date: [REDACTED] +0
Location: [REDACTED]

Supplemental Report

[REDACTED] +418

PCR for mutation in exons 18-21 of the EGFR gene was performed at [REDACTED] on sections from the formalin fixed paraffin block 2B of the lung wedge resection specimen.

The result is **mutation of the EGFR gene is DETECTED** (see attached report from [REDACTED])

Physicians

Tissue Source

1. LUNG, left lower lobe-Bronchial Biopsy
2. LUNG, left lower lobe-Wedge Resection
3. LUNG, left lower lobe, additional-Wedge Resection
4. LYMPH NODE, level 8-Excisional Biopsy
5. LUNG, left, lower lobe-Lobectomy

Clinical Information

1. -5. Lesion of lung

Diagnosis

1. LUNG, left lower lobe-Bronchial Biopsy
LUNG TISSUE WITH SQUAMOUS METAPLASIA
2. LUNG, left lower lobe-Wedge Resection
**ADENOCARCINOMA, POORLY DIFFERENTIATED, WITH ASSOCIATED SCAR AND EXTENDING INTO ADJACENT AIR SPACES.
(SEE SYNOPTIC REPORT)**
3. LUNG, left lower lobe, additional-Wedge Resection

S
U
R
G
I
C
A
L

P
A
T
H
O
L
O
G
Y

R
E
P
O
R
T

[page 4 of 13]
Diagnosis (continued)

LUNG TISSUE WITH FOCAL HYPERPLASTIC PNEUMOCYTES, FOCAL ATELECTASIS, ABUNDANT PIGMENTED INTRA-ALVEOLAR MACROPHAGES AND VASCULAR CONGESTION, NEGATIVE FOR TUMOR.

4. LYMPH NODE, level 8-Excisional Biopsy
LYMPH NODE, NEGATIVE FOR TUMOR (0/1)

5. LUNG, left, lower lobe-Lobectomy
SEGMENT OF LUNG WITH FOCAL ATELECTASIS, PERIBRONCHIAL ACUTE AND CHRONIC INFLAMMATION, VASCULAR CONGESTION AND ABUNDANT INTRAALVEOLAR PIGMENTED MACROPHAGES, NEGATIVE FOR TUMOR
BRONCHIAL AND VASCULAR MARGINS OF RESECTION, NEGATIVE FOR TUMOR
PERIBRONCHIAL LYMPH NODE, NEGATIVE FOR TUMOR (0/1).

+5

Tumor Staging Synoptic Report

2. .
MACROSCOPIC SUMMARY: Lung
Specimen Type: Lobectomy
Tumor Site: Left, Lower lobe
Tumor Greatest Dimension: 1.7 cm

MICROSCOPIC SUMMARY: .
Histologic Type: Adenocarcinoma, NOS
Histologic Grade: G3: Poorly differentiated
Extent Of Invasion: T1: Tumor 3 cm or less in greatest dimension, surrounded by lung or visceral pleura, without bronchoscopic evidence of invasion more proximal than the lobar bronchus (ie. not in the main bronchus)
Focality: Unifocal
Margins: Uninvolved by invasive carcinoma
Nearest Margin/Distance: visceral pleura/0.3 cm
Blood/Lymphatic Vessel Invasion: Present
Venous Invasion: Indeterminate
Regional Lymph Nodes: N0: No regional lymph node metastasis
Nodes Examined: 2 (1 peribronchial lymph node and 1 level 8 lymph node)
Nodes Involved: 0
Distant Metastasis: MX: Cannot be assessed
Direct Extension Of Tumor: Not observed
Pathologic Stage Grouping: pT1aN0MX
Additional Pathologic Findings: Mild chronic inflammatory response
Atypical alveolar epithelial cell proliferation

COMMENT:
Micropapillary features with rare psammoma bodies.
Aerogenous spread of tumor into the neighboring air spaces

S
U
R
G
I
C
A
L

P
A
T
H
O
L
O
G
Y

R
E
P
O
R
T

[page 5 of 13]
Gross Description

1. Received fresh by the pathologist in the operating room, labeled "left lower lobe lesion" are 2 friable fragments of tan-gray tissue which are submitted in toto for frozen section examination. The frozen section residue is resubmitted as FS. 1/multiple [REDACTED]

Frozen Section Interpretation

Received are a few portions of tan pink tissue which are entirely frozen.

FSDX: Bronchial mucosa with atypical squamous metaplasia. Separate fragment of lung tissue negative for tumor.

+0

2. Received fresh by the pathologist in the operating room, labeled "left lower lobe" is a 21 gram, 9 x 3 x 2 cm wedge-shaped segment of lung which has been previously incised by the surgeon. In the region of the incision, there is a 1.3 x 1.2 cm well-circumscribed tan-gray, subpleural mass. A portion of the mass is submitted for frozen section examination. The overlying pleura is subsequently inked. The remaining cut surfaces are markedly congested dark red and grossly unremarkable. The frozen section residue is resubmitted as [REDACTED]. Additional sections are submitted as follows: A and B, remainder of mass; C, intraparenchymal staple line margin; D, congested lung parenchyma. 5/multiple [REDACTED]

Frozen Section Interpretation

Received is a 9 x 2 x 2 cm wedge of lung with a previously incised 1.3 cm tan grey mass. A section of the mass is submitted for frozen section.

FS DX: Non small cell carcinoma

3. Received in formalin, labeled "additional left lower lobe" is a 12 gram, 7.5 x 2.8 x 1 cm wedge-shaped segment of lung tissue which is stapled along one aspect. The specimen has been previously incised by the surgeon to reveal congested dark red parenchyma with no distinct lesion. The pleural surface is congested red-purple and smooth. On further sectioning, the parenchyma is markedly congested and does not contain lesions or nodules. Sections are submitted as follows: A and B, lung parenchyma in incised area; C, additional lung parenchyma; D, intraparenchymal staple line. [REDACTED]
4. Received in formalin, labeled "level 8 lymph node" is a 1 x 0.9 x 0.3 cm gray-black, rubbery portion of tissue which is submitted in toto. [REDACTED]
5. Received in formalin, labeled "left lower lobe completion lobectomy" is a 209 gram, 18.5 x 10.5 x 4 cm irregularly shaped, markedly stapled portion of lung consistent with the left lower lobe. On sectioning adjacent to one staple

S
U
R
G
I
C
A
L

P
A
T
H
O
L
O
G
Y

R
E
P
O
R
T

[page 6 of 13]
Gross Description (continued)

lines, the bronchial and vascular margin is identified. Superior aspect of the specimen is markedly distorted and stapled. On sectioning the basilar segment, the cut surfaces are markedly congested dark red-purple parenchyma with no distinct lesions. A few possible peribronchial lymph nodes are identified at the margin. Sections are submitted as follows: A, bronchial and vascular margin; B., possible peribronchial lymph nodes; C, superior segment; D and E, basilar segment.

Image

SURGICAL PATHOLOGY REPORT

PATIENT INFORMATION		REPORT STATUS
[REDACTED]		Final
SPECIMEN INFORMATION		
SPECIMEN:	DOB:	Age:
ACQUISITION:	SEX:	[REDACTED]
LAB REF NO:	ID:	[REDACTED]
COLLECTOR:	PHONE:	[REDACTED]
RECEIVED:	[REDACTED]	
REPORTED:	[REDACTED]	

Test Name	In Range	Out of Range	Reference Range	Lab
Epidermal Growth Factor Receptor (EGFR) Mutation				
Epidermal Growth Factor Receptor (EGFR) Mutation				
Specimen Source:	LUNG, LEFT LOWER LOBE-WEDGE RESECTION			
Specimen/Block Number:	[REDACTED]			
EGFR Mutation:	Detected			
Mutation Type:	p.L858R_P753S, c.2240_2251del, mixed/heterozygous in exon 19.			
Results reviewed by:	[REDACTED]			

Mutations of this type are common in EGFR in lung cancer and are associated with response to EGFR-directed tyrosine kinase inhibitors.

EGFR kinase domain mutations are found in 10-15% of lung adenocarcinomas, particularly those occurring in younger patients without a smoking history, and identify tumors that may have significant clinical response to EGFR-targeted kinase inhibitors. Secondary somatic mutations in EGFR, particularly T790M in exon 20, may accompany acquired resistance to these inhibitors.

Genomic DNA was extracted from microdissected paraffin-embedded tissue sections isolated from the submitted block. PCR-based DNA sequencing was used to assess for mutations in exons 18-21 of EGFR, which are the sites of greater than 95% of somatic mutations observed in tumors. The sensitivity for mutation detection of the assay is 10% mutant allele in the background of normal allele in the microdissected area.

The reference range for EGFR mutation in non-neoplastic tissues is not detected.

This test was developed and its performance characteristics have been determined by [REDACTED]. Performance characteristics refer to the [REDACTED].

[page 7 of 13]
PROTOCOL #9671

PATIENT INFORMATION

REPORT STATUS Final

COLLECTED
REPORTED:

DOB: Age: SEX: PO:

RECEIVED COLLECTION

Test Name	In Range	Out of Range	Reference Range	Lab
-----------	----------	--------------	-----------------	-----

Epidermal Growth Factor Receptor (EGFR) Mutation (Continued)

Results reviewed by: (Continued)

analytical performance of the test.

S
U
R
G
I
C
A
L

P
A
T
H
O
L
O
G
Y

R
E
P
O
R
T

Page 2 - End of Report

Charges by Specimen
Specimen

Code

CPT

Count

Supplemental copy

[page 8 of 13]
Class: Outpatient
Accession: [REDACTED]
PET CT Skull to Thigh Area
Subsequent
Reason for Exam: lung Ca; new
lytic spine lesions - ONS
Date: [REDACTED]

+396

Imaging Result

HISTORY: [REDACTED] female with lung cancer and new lytic spine lesions. The patient is referred for restaging.

TECHNIQUE: The patient's blood glucose level was measured to be 105 mg/dL. At approximately one hour following intravenous injection of 12.6 mCi of 18 F-fluorodeoxyglucose, an attenuation corrected PET scan was performed from the orbits to the proximal femora. Low dose CT imaging was utilized for attenuation correction and anatomic localization. Comparison is made to a previous study of [REDACTED] -3

FINDINGS: There is a focus of abnormally increased tracer accumulation in the left occipital condyle demonstrating a maximum standard uptake value of 8.0. This finding is suspicious for an osseous metastasis. Physiologic salivary activity is present in the oropharynx. No abnormal focus or region of tracer accumulation is seen in the neck.

In the thorax, there is a 4.5 cm diameter area of increased tracer accumulation in the medial aspect of the left scapula in association with a permeative lytic lesion. Maximum standard uptake value of this finding is 4.7. In the manubrium of the sternum there is a 2.5 cm diameter area of increased tracer accumulation of maximum standard uptake value 7.6. Within the T6 vertebra is an area of increased tracer accumulation with a maximum standard uptake value of 5.5. In the right aspect of the T9 vertebra including the pedicle and transverse process, abnormal tracer accumulation is seen of maximum standard uptake value 7.4. Other smaller osseous lesions are seen in the thoracic spine and ribs. These findings are consistent with malignancy.

Physiologic mediastinal blood pool activity and physiologic left ventricular activity are demonstrated. There is no other abnormal focus or region of tracer accumulation in the thorax to indicate malignancy.

In the abdomen, physiologic hepatic, splenic and gastric activity are demonstrated. Tracer excretion is seen in the kidneys ureters and bladder, the normal route of tracer excretion. Multiple foci of abnormal tracer accumulation are seen in vertebra of the lumbar spine. A focus of increased tracer accumulation is demonstrated in the medial right ilium on image 179. In the left ilium there is a region of abnormal tracer accumulation of approximately 5.9 cm diameter associated with an area of sclerosis. The maximum standard uptake value in this location is 5.9.

Physiologic colonic activity is demonstrated. There is no other abnormal focus or region of tracer accumulation in the abdomen or pelvis to indicate evidence of malignancy.

Review of the attenuation correction CT images was performed. There is evidence of previous left thoracic surgery. There is an area of consolidation or atelectasis in the central and inferior right lower lobe. A heterogeneous densely calcified fibroid of 5.3 cm diameter is demonstrated in the pelvis.

[page 9 of 13]
1. Multiple osseous lesions are demonstrated in the left occipital condyle, left scapula, thoracic and lumbar spine, sternum, and ilia. These findings represent an interval change compared to the previous study and are consistent with interval progression of disease.

2. There is an area of atelectasis or consolidation in the central and inferior portions of the right lower lobe.
3. No other definite malignancy is demonstrated by PET.

Reported And Signed By

[REDACTED]

[page 10 of 13]
[REDACTED] PROTOCOL #9671 [REDACTED]

[REDACTED]

[REDACTED]

Class: Outpatient
Accession: [REDACTED]
PET CT Skull to Thigh Area
Subsequent
Reason for Exam: lung ca f/u
Date: [REDACTED]

+651

Imaging Result

HISTORY: [REDACTED] female with history of lung cancer referred for restaging.

TECHNIQUE: The patient's blood glucose level was measured to be 106 mg/dL. At approximately one hour following intravenous injection of 10.4 mCi of 18 F-fluorodeoxyglucose, an attenuation corrected PET scan was performed from the orbits to the proximal femora. Low dose CT imaging was utilized for attenuation correction and anatomic localization. Comparison is made to a previous study of [REDACTED] +536

FINDINGS: There is head motion during imaging. Physiologic salivary activity is present in the oropharynx. Physiologic laryngeal activity is noted. No abnormal focus or region of tracer accumulation is seen in the neck.

In the thorax, physiologic mediastinal blood pool activity and physiologic left ventricular activity are demonstrated. There is no abnormal focus or region of tracer accumulation in the thorax to indicate malignancy.

In the abdomen, physiologic hepatic, splenic and gastric activity are demonstrated. Tracer excretion is seen in the kidneys ureters and bladder, the normal route of tracer excretion. Physiologic colonic activity is demonstrated. There is no abnormal focus or region of tracer accumulation in the abdomen or pelvis to indicate evidence of malignancy.

Review of the attenuation correction CT images was performed. A calcified uterine fibroid is demonstrated in the pelvis measuring 5.4 cm diameter. Multiple sclerotic densities are seen throughout the skeleton consistent with osseous metastatic lesions. These do not demonstrate abnormal tracer accumulation on the PET images.

IMPRESSION:

1. No definite malignancy demonstrated by PET.
2. Diffuse sclerotic lesions of the skeletal structures are present without definite change compared to the previous study. These findings do not demonstrate abnormal tracer accumulation on the PET images.
- [REDACTED]
- [REDACTED]
- [REDACTED]

[page 11 of 13]
Name: [REDACTED]
MRN: [REDACTED]
DOB: [REDACTED]
Class: Outpatient
Accession: [REDACTED]
PET CT Skull to Thigh Area
Subsequent
Reason for Exam: met lung ca
Date: [REDACTED]

+771

Imaging Result

HISTORY: [REDACTED] with lung cancer and osseous metastases. Evaluate for interval change.

TECHNIQUE: The patient's blood glucose level was measured to be 97 mg/dL. At approximately one hour following intravenous injection of 10.2 mCi of 18 F-fluorodeoxyglucose, an attenuation corrected PET scan was performed from the orbits to the proximal femora. Low dose CT imaging was utilized for attenuation correction and anatomic localization. Comparison is made to a previous study of [REDACTED] +651

FINDINGS: Physiologic salivary activity is present in the oropharynx. No abnormal focus or region of tracer accumulation is seen in the neck.

In the thorax, physiologic mediastinal blood pool activity and physiologic left ventricular activity are demonstrated. There is a new small focus of increased tracer accumulation projecting within the second rib demonstrated on PET/CT image 47. The maximum standard uptake value of this lesion is 2.3. There is no other abnormal focus or region of tracer accumulation in the thorax to indicate malignancy.

In the abdomen, physiologic hepatic, splenic and gastric activity are demonstrated. Tracer excretion is seen in the kidneys ureters and bladder, the normal route of tracer excretion. Physiologic colonic activity is demonstrated. Within the posterior aspect of the L4 vertebral body as demonstrated on PET/CT image 152 is a new focus of increased tracer accumulation of maximum standard uptake value 3.9. There is no other abnormal focus or region of tracer accumulation in the abdomen or pelvis to indicate evidence of malignancy.

Review of the attenuation correction CT images was performed. Calcified fibroids of the uterus are again demonstrated. Postoperative changes of the left hemithorax are demonstrated. Multiple sclerotic densities are again demonstrated throughout the skeletal structures, not demonstrating abnormal tracer accumulation on the PET series but consistent with osseous metastatic lesions.

IMPRESSION:

1. New abnormal tracer accumulation is demonstrated in the left second rib and in the L4 vertebral body consistent with mild interval progression of osseous metastases.
2. No other definite malignancy is demonstrated by PET.
3. Diffuse sclerotic lesions of the skeletal structures which do not demonstrate abnormal tracer accumulation are again demonstrated.

Reported And Signed By: [REDACTED]

[REDACTED]

[page 12 of 13]
[REDACTED]

[REDACTED]

[REDACTED]

[page 13 of 13]
ER-ABOM-TTP1-PR Redacted

Patient Name: [REDACTED]
MR #: [REDACTED] Account: [REDACTED]
Date of Birth: [REDACTED] Age: [REDACTED] Sex: [REDACTED]
Submitting [REDACTED]

Case Number: [REDACTED]
Collection Date:
Received Date:
Location:

Physicians
REGISTRY, TUMOR;

Tissue Source
CYTOLOGY FNA, lung, left lower lobe-Fine Needle Aspiration

Clinical Information
Lesion of lung

Gross Description
Received fresh by the pathologist in Radiology is a fine needle aspirate of the lung, left lower lobe. Needle washings (utilizing cytolyt) of 15 cc's of pink fluid are obtained. One Thin Prep is prepared from the needle washing material. Ten air-dried slides were prepared and stained with

ICD-D-3
adenocarcinoma, NOS 8140/3
Site: ① lower lobe lung c 34.3

ICD-10 ^{hw}
c 34.32 7/10/15

Immediate Cytologic Evaluation

Received are 8 air dried slides which are stained with

Immediate Cytologic Interpretation: Few atypical cells and benign bronchial epithelial cells.

C
Y
T
O
L
O
G
Y

R
E
P
O
R
T

Diagnosis
CYTOLOGY FNA, lung, left lower lobe-Fine Needle Aspiration
POSITIVE FOR MALIGNANCY
RARE VARIABLY SIZED GROUPS OF CELLS COMPATIBLE WITH ADENOCARCINOMA
(SEE COMMENT AND CONCURRENT RESECTION SPECIMEN

Source: NCI Genomic Data Commons file c9aebf09-3577-47c3-bd15-bee28cef5957 (ER0190 ER-ABOM Clinical Report_Redacted_Sanitized.pdf), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).